CCDI case PBCBGH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/66518337-9e0f-4b86-9264-b9b62a3afa90

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.7 years (606 days).

Biospecimens (3 samples)
- Sample 0DPH9W: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPHA4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPHAA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
